Gene-level copy-number profile of tumor specimen HCM-CSHL-0064-C18-01A from HCMI case HCM-CSHL-0064-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.4 years (27,552 days).
Specimen HCM-CSHL-0064-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67bf8e5b-509f-4291-a8fd-e1aac51500c1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0064-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/cc2133b7-38b2-405f-b08f-1070c66655cd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 541; copy number 1: 759; copy number 2: 4,215; copy number 3: 14,564; copy number 4: 25,239; copy number 5: 7,435; copy number 6: 3,837; copy number 7: 1,443; copy number 9: 817; copy number 11: 45; copy number 13: 15.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,326,201–2,326,693, 1 gene (within-gene range 0–3): AL589739.1.
- chr4:184,471,924–185,370,185, 26 genes (within-gene range 0–2): AC099343.2, IRF2-DT, LINC02427, AC099343.1, LINC02365, CASP3, PRIMPOL, CENPU, ACSL1, SLED1, AC084871.1, AC084871.3, MIR3945HG, MIR3945, LINC01093, AC084871.2, MIR4455, AC112243.1, LINC02437, HELT, LINC02436, AC093824.1, AC093824.2, SLC25A4, CFAP97, SNX25.
- chr6:162,568,379–162,569,728, 1 gene (within-gene range 0–4): KRT8P44.
- chr15:41,825,099–41,827,936, 1 gene (within-gene range 0–2): AC020659.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 877 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:26,103,416–64,327,972, 872 genes, copy number 9–13 (broad region; genes not listed).
- chr21:12,999,676–13,120,807, 5 genes, copy number 9: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
